Somatic mutation profile of tumor specimen C3N-02288-03 (aliquot CPT0186130006) from CPTAC case C3N-02288, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 58.7 years (21,432 days).
Specimen C3N-02288-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5d1f422-77b7-49a2-b6fc-e01ec6b72394.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02288-31 (Blood Derived Normal), aliquot CPT0186170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3ec31a9-406c-40a9-8aa0-a3de8d60e207

The open-access MAF lists 275 somatic variants for this specimen: 173 protein-altering or splice-affecting, 57 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 57, Nonsense Mutation 16, Intron 15, 3'UTR 9, RNA 9, 5'Flank 7, Splice Site 6, Frame Shift Del 5, 5'UTR 4, Frame Shift Ins 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- ADAMTS20 | c.332C>A p.T111N | Missense Mutation (SNP) | VAF 97/464 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs748772832; called by muse, mutect2, varscan2
- ANO3 | c.1834C>G p.L612V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56790495, COSV56807883; called by muse, mutect2, varscan2
- ANPEP | c.898-1G>T p.X300_splice | Splice Site (SNP) | VAF 28/127 reads (22%) | catalogued as COSV55591079; called by muse, mutect2, varscan2
- ASTN1 | c.809G>C p.R270P | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56065847; called by muse, mutect2, varscan2
- C8B | c.1031A>G p.Y344C | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV64776352; called by muse, mutect2, varscan2
- CCDC138 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as rs1478700400; called by muse, mutect2, varscan2
- CCDC153 | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 131/544 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100501245; called by muse, mutect2, varscan2
- CNTN5 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 44/581 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.04); catalogued as COSV54347225; called by muse, mutect2
- CSMD1 | c.5290G>A p.V1764I (on ENST00000520002; = p.V1763I on NM_033225.6) | Missense Mutation (SNP) | VAF 57/474 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs752235970, COSV59344777; called by muse, mutect2, varscan2
- DCAF12L2 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100758493, COSV63582439, COSV63582926; called by muse, mutect2, varscan2
- FAM227B | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54814682; called by muse, mutect2, varscan2
- FEM1A | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 23/348 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1359671939; called by muse, mutect2
- FURIN | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV51579977; called by muse, mutect2, varscan2
- FUT5 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 71/506 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs756192247, COSV53138665; called by muse, mutect2, varscan2
- FUT5 | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 73/507 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.222); catalogued as rs745747279, COSV53138351; called by muse, mutect2, varscan2
- GFUS | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 17/403 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as rs902589816; called by muse, mutect2
- INSRR | c.113A>T p.E38V | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV63874587; called by muse, mutect2, varscan2
- JAK3 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs896064879, COSV71688281; called by muse, mutect2
- KIF4B | c.2137C>T p.R713* | Nonsense Mutation (SNP) | VAF 21/216 reads (10%) | catalogued as rs200206658, COSV70528996; called by muse, mutect2
- KIF7 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 158/620 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs148779858; called by muse, mutect2, varscan2
- LEUTX | c.423G>T p.L141F | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs926899678; called by muse, mutect2, varscan2
- LRRN3 | c.1129C>G p.R377G | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100073522, COSV57818023; called by muse, mutect2, varscan2
- MRGPRX3 | c.485A>C p.D162A | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV66933563; called by muse, mutect2, varscan2
- MYO5B | c.3685C>A p.Q1229K | Missense Mutation (SNP) | VAF 158/470 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV53225375; called by muse, mutect2, varscan2
- NAV3 | c.5597C>G p.P1866R (on ENST00000397909 / NM_001024383.2; = p.P1844R on NM_014903.6) | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV57081316; called by muse, mutect2, varscan2
- NCSTN | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 164/600 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV54187669; called by muse, mutect2, varscan2
- NEFM | c.2410G>T p.G804W | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV55334829; called by muse, mutect2, varscan2
- OR2AG2 | c.392A>C p.K131T | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs200591320; called by muse, mutect2, varscan2
- PCDH19 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 248/724 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM1511993, COSV55263862; called by muse, mutect2, varscan2
- PCDH8 | c.2299A>G p.I767V | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs750249806; called by muse, mutect2, varscan2
- PPP1R13B | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376467189; called by muse, mutect2, varscan2
- PRR23C | c.334T>A p.S112T | Missense Mutation (SNP) | VAF 82/422 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.228); catalogued as rs772693498; called by muse, varscan2
- PRRC2A | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1379024118; called by muse, mutect2, varscan2
- PTPN13 | c.5806G>T p.G1936* (on ENST00000411767 / NM_080683.3; = p.G1917* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 55/187 reads (29%) | catalogued as COSV100364694; called by muse, mutect2, varscan2
- RNF10 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 57/236 reads (24%) | catalogued as COSV58047590; called by muse, mutect2, varscan2
- SCYL3 | c.2188G>A p.E730K (on ENST00000367770; = p.E676K on NM_020423.7) | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1327875193; called by muse, mutect2, varscan2
- SLIT3 | c.3032G>T p.C1011F | Missense Mutation (SNP) | VAF 101/351 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM138095; called by muse, mutect2, varscan2
- TPSAB1 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 38/154 reads (25%) | catalogued as rs749741287; called by muse, mutect2, varscan2
- TREML4 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58385380; called by muse, mutect2, varscan2
- TRIM64C | c.54C>A p.C18* | Nonsense Mutation (SNP) | VAF 60/275 reads (22%) | catalogued as COSV99081832; called by muse, mutect2, varscan2
- USH2A | c.5678C>A p.S1893* | Nonsense Mutation (SNP) | VAF 84/266 reads (32%) | catalogued as COSV56438920; called by muse, mutect2, varscan2
- ZFYVE9 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV55101777; called by muse, mutect2, varscan2
- ZNF521 | c.3202G>T p.A1068S | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV100831401, COSV64132210; called by muse, mutect2, varscan2
- ZNF600 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 41/85 reads (48%) | catalogued as COSV100592889; called by muse, mutect2, varscan2
- ZNF676 | c.1663C>A p.H555N (on ENST00000650058; = p.H523N on NM_001001411.3) | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1457320488; called by muse, mutect2, varscan2
- ABCA4 | c.6310C>A p.Q2104K | Missense Mutation (SNP) | VAF 232/464 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ABTB1 | c.665G>A p.C222Y (on ENST00000232744 / NM_172027.3; = p.C80Y on NM_032548.3) | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.025); called by muse, mutect2
- ACVR1 | c.361C>A p.H121N | Missense Mutation (SNP) | VAF 128/309 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKLE2 | c.1250A>G p.H417R | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANKMY1 | c.2327A>T p.E776V | Missense Mutation (SNP) | VAF 174/381 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2B1 | c.2731C>T p.L911F | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP6AP1 | c.1235T>A p.F412Y | Missense Mutation (SNP) | VAF 162/509 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATRX | c.3262G>T p.G1088C | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- ATRX | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCAT2 | c.845A>G p.E282G | Missense Mutation (SNP) | VAF 100/258 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BMS1 | c.2648G>T p.G883V | Missense Mutation (SNP) | VAF 24/373 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C6 | c.1063A>T p.S355C | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CBLB | c.2837T>C p.F946S | Missense Mutation (SNP) | VAF 99/453 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CC2D1A | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CCDC62 | c.1684A>G p.T562A | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, varscan2
- CCDC85C | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 120/340 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CD46 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- CENPM | c.4T>A p.S2T | Missense Mutation (SNP) | VAF 63/362 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- CEP162 | c.1433A>T p.E478V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- CLEC4F | c.500A>G p.Q167R | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CRISPLD1 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.157); called by muse, mutect2
- CRYGA | c.95G>C p.R32P | Missense Mutation (SNP) | VAF 106/616 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CTH | c.239G>C p.G80A | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CTNND2 | c.2330C>T p.A777V | Missense Mutation (SNP) | VAF 83/318 reads (26%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CUX1 | c.3916G>C p.E1306Q | Missense Mutation (SNP) | VAF 206/621 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- DCAF8L2 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DEPDC1 | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DIP2C | c.310A>G p.K104E | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- DMGDH | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- DNAH7 | c.8697G>T p.Q2899H | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DRC1 | c.853A>C p.N285H | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DUSP26 | c.334C>A p.R112S | Missense Mutation (SNP) | VAF 149/586 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EHMT2 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- EYS | c.3721A>T p.R1241W | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, varscan2
- FLVCR2 | c.65A>T p.Q22L | Missense Mutation (SNP) | VAF 274/741 reads (37%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRQ | c.1177del p.E393Kfs*25 | Frame Shift Del (DEL) | VAF 47/149 reads (32%) | called by mutect2, pindel, varscan2
- GCKR | c.568C>A p.Q190K | Missense Mutation (SNP) | VAF 320/873 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- GFI1 | c.1085A>G p.H362R | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPC4 | c.822G>T p.M274I | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, varscan2
- GRB10 | c.1465A>G p.R489G (on ENST00000398812; = p.R443G on NM_001001549.3) | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HCN1 | c.2324A>T p.H775L | Missense Mutation (SNP) | VAF 136/400 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HECW2 | c.1234C>G p.R412G | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- INTS3 | c.2245-1G>A p.X749_splice | Splice Site (SNP) | VAF 66/207 reads (32%) | called by muse, mutect2, varscan2
- IQSEC3 | c.1139del p.P380Rfs*103 (on ENST00000538872 / NM_001170738.2; = p.P77Rfs*103 on NM_015232.1) | Frame Shift Del (DEL) | VAF 93/421 reads (22%) | called by mutect2, pindel, varscan2
- IRX5 | c.1018A>G p.I340V | Missense Mutation (SNP) | VAF 136/629 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- KLHL12 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC53 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRRC7 | c.4069A>C p.T1357P | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LYPD5 | c.478C>T p.Q160* (on ENST00000377950 / NM_001031749.3; = p.Q117* on NM_182573.2) | Nonsense Mutation (SNP) | VAF 70/579 reads (12%) | called by muse, mutect2, varscan2
- MAGEA11 | c.267-1G>T p.X89_splice | Splice Site (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- MAPK6 | c.1302A>T p.K434N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MSX1 | c.96_119del p.P33_A40del | In Frame Del (DEL) | VAF 50/263 reads (19%) | called by mutect2, pindel, varscan2
- MUC12 | c.12452C>T p.S4151F (on ENST00000379442; = p.S4008F on NM_001164462.1) | Missense Mutation (SNP) | VAF 154/3178 reads (5%) | SIFT tolerated (0.27); called by muse, mutect2
- MUC17 | c.7490C>A p.P2497H | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- MZT2B | c.469A>T p.S157C | Missense Mutation (SNP) | VAF 110/223 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- NME7 | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NPAS4 | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- NPBWR2 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 144/742 reads (19%) | called by muse, mutect2, varscan2
- OCRL | c.2522C>G p.A841G | Missense Mutation (SNP) | VAF 88/267 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- OCSTAMP | c.55T>C p.W19R | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- OR2A25 | c.553A>T p.K185* | Nonsense Mutation (SNP) | VAF 60/219 reads (27%) | called by muse, mutect2, varscan2
- OR2L13 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 119/274 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR2M4 | c.289T>G p.C97G | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- OR56A5 | c.65G>C p.S22T | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR56B1 | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OR5H15 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCDHB10 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PCGF2 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 116/213 reads (54%) | called by muse, mutect2, varscan2
- PHLPP1 | c.4294T>A p.C1432S | Missense Mutation (SNP) | VAF 100/290 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PIBF1 | c.1098-2A>G p.X366_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- PIK3C2B | c.2772G>A p.Q924= | Splice Region (SNP) | VAF 93/322 reads (29%) | called by muse, mutect2, varscan2
- PISD | c.1040G>A p.G347D (on ENST00000439502 / NM_001326412.1; = p.G313D on NM_014338.3) | Missense Mutation (SNP) | VAF 67/298 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- PLAC1 | c.525G>T p.Q175H | Missense Mutation (SNP) | VAF 122/438 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- PLEKHA7 | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLXNB2 | c.1517_1531del p.E506_L511delinsV | In Frame Del (DEL) | VAF 69/364 reads (19%) | called by mutect2, pindel, varscan2
- POU6F1 | c.1518G>T p.K506N | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PREB | c.1042del p.D348Mfs*57 | Frame Shift Del (DEL) | VAF 102/353 reads (29%) | called by mutect2, pindel, varscan2
- PROCR | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 151/709 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- PRR23A | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 268/696 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- PRTG | c.2624-1G>A p.X875_splice | Splice Site (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- RALGPS2 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RANBP2 | c.190A>T p.R64* | Nonsense Mutation (SNP) | VAF 133/340 reads (39%) | called by muse, mutect2, varscan2
- RIOK1 | c.1108A>T p.R370W | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- RTL1 | c.3934G>T p.E1312* | Nonsense Mutation (SNP) | VAF 184/518 reads (36%) | called by muse, mutect2, varscan2
- RYR2 | c.754C>A p.H252N | Missense Mutation (SNP) | VAF 108/281 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- SALL1 | c.986C>A p.T329N | Missense Mutation (SNP) | VAF 85/393 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SCARF1 | c.935A>T p.H312L | Missense Mutation (SNP) | VAF 299/610 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SCN5A | c.4322A>G p.E1441G (on ENST00000333535 / NM_198056.3; = p.E1440G on NM_000335.5) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SEMA3D | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SH3PXD2A | c.3196T>A p.S1066T (on ENST00000369774 / NM_001365079.1; = p.S1038T on NM_014631.2) | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SIL1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- SLC14A1 | c.376G>C p.A126P | Missense Mutation (SNP) | VAF 194/486 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SLC16A3 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 214/404 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A14 | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, varscan2
- SLFN12 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SMPD4 | c.711_712insT p.E238* | Frame Shift Ins (INS) | VAF 18/100 reads (18%) | called by mutect2, pindel, varscan2
- SNRPB2 | c.430-1G>A p.X144_splice | Splice Site (SNP) | VAF 34/285 reads (12%) | called by muse, mutect2, varscan2
- SNRPB2 | c.430G>T p.V144F | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SPATS1 | c.800dup p.N267Kfs*2 | Frame Shift Ins (INS) | VAF 38/180 reads (21%) | called by mutect2, pindel, varscan2
- SPCS3 | c.321C>G p.D107E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPZ1 | c.1204A>T p.N402Y | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SRRM4 | c.1751G>T p.R584L | Missense Mutation (SNP) | VAF 141/603 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ST8SIA1 | c.888G>T p.W296C | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAB2 | c.4945T>A p.W1649R | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYDE2 | c.2874G>C p.L958F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- SZRD1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 77/221 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TCP11L2 | c.1098G>T p.R366S | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- TINAG | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLL1 | c.2025T>G p.Y675* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- TMEM135 | c.1345G>A p.V449I | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- TMEM229A | c.684G>T p.R228S | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIM27 | c.1043C>G p.P348R | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC29 | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 144/484 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTPA | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- TYR | c.439T>A p.S147T | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UHRF1BP1L | c.2318A>G p.Y773C | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- UNC5C | c.298G>C p.V100L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); called by muse, mutect2
- USH2A | c.11032C>T p.Q3678* | Nonsense Mutation (SNP) | VAF 113/409 reads (28%) | called by muse, mutect2, varscan2
- UTP14A | c.1798del p.A600Lfs*10 | Frame Shift Del (DEL) | VAF 78/360 reads (22%) | called by mutect2, pindel, varscan2
- VWC2L | c.233G>T p.C78F | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR19 | c.1954A>T p.M652L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- ZDHHC9 | c.792G>A p.W264* | Nonsense Mutation (SNP) | VAF 15/230 reads (7%) | called by muse, mutect2
- ZFHX4 | c.4862C>A p.A1621D | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF385A | c.353G>T p.R118L (on ENST00000338010 / NM_001130967.3; = p.R98L on NM_015481.3) | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- ZNF541 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 37/1036 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.54); called by muse, mutect2
- ZNF587 | c.1259G>A p.R420K | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF676 | c.1662A>C p.E554D (on ENST00000650058; = p.E522D on NM_001001411.3) | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ACSM2A | c.258G>C p.L86= (on ENST00000219054; = p.L7= on NM_001308169.2) | Silent (SNP) | VAF 56/672 reads (8%) | called by muse, mutect2
- ACSM2B | c.258G>C p.L86= | Silent (SNP) | VAF 20/132 reads (15%) | called by muse, mutect2, varscan2
- ACVR1 | c.360C>T p.F120= | Silent (SNP) | VAF 128/311 reads (41%) | called by muse, mutect2, varscan2
- ADGRL1 | c.2259G>T p.P753= (on ENST00000340736 / NM_001008701.3; = p.P748= on NM_014921.5) | Silent (SNP) | VAF 272/756 reads (36%) | catalogued as rs562136668; called by muse, varscan2
- ARAP3 | c.2556G>C p.R852= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- ATP1A4 | c.2289C>T p.S763= | Silent (SNP) | VAF 87/343 reads (25%) | called by muse, mutect2, varscan2
- ATP8B3 | c.664C>T p.L222= | Silent (SNP) | VAF 30/292 reads (10%) | catalogued as rs756227526; called by muse, mutect2, varscan2
- BIRC6 | c.3516A>G p.P1172= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2
- BSG | c.945G>A p.T315= | Silent (SNP) | VAF 104/835 reads (12%) | catalogued as rs773330019, COSV100344718; called by muse, mutect2, varscan2
- C2CD4B | c.561G>A p.A187= | Silent (SNP) | VAF 57/267 reads (21%) | called by muse, mutect2, varscan2
- CCDC85C | c.912G>A p.S304= | Silent (SNP) | VAF 80/412 reads (19%) | called by muse, mutect2, varscan2
- CDH12 | c.1983T>C p.D661= | Silent (SNP) | VAF 66/224 reads (29%) | called by muse, mutect2, varscan2
- CIT | c.768C>A p.L256= | Silent (SNP) | VAF 45/199 reads (23%) | catalogued as rs1386505503; called by muse, mutect2, varscan2
- CNTN5 | c.954T>A p.V318= | Silent (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- CUL7 | c.2145G>C p.L715= | Silent (SNP) | VAF 89/388 reads (23%) | called by muse, mutect2, varscan2
- CYP4X1 | c.1170G>A p.K390= | Silent (SNP) | VAF 69/266 reads (26%) | called by muse, mutect2, varscan2
- CYTIP | c.1012C>A p.R338= | Silent (SNP) | VAF 59/131 reads (45%) | catalogued as COSV99938912; called by muse, mutect2, varscan2
- HAO1 | c.579T>C p.F193= | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as COSV101113174, COSV66491698; called by muse, mutect2
- HFM1 | c.4110A>T p.P1370= | Silent (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- HLA-A | c.624C>T p.P208= | Silent (SNP) | VAF 37/263 reads (14%) | catalogued as COSV65142092; called by muse, mutect2, varscan2
- HTR2C | c.750C>T p.H250= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as rs1176307693, COSV52203838, COSV52221497; called by muse, mutect2
- IGKV1-17 | c.96C>A p.S32= | Silent (SNP) | VAF 71/966 reads (7%) | catalogued as rs748023822; called by muse, mutect2
- IL9R | c.1401C>T p.I467= | Silent (SNP) | VAF 51/205 reads (25%) | called by muse, mutect2, varscan2
- INSYN1 | c.636G>A p.E212= | Silent (SNP) | VAF 39/175 reads (22%) | catalogued as rs1411444921, COSV65837993; called by muse, mutect2, varscan2
- KCNC2 | c.972A>G p.L324= | Silent (SNP) | VAF 47/236 reads (20%) | called by muse, mutect2, varscan2
- KIF16B | c.99G>C p.T33= | Silent (SNP) | VAF 20/248 reads (8%) | catalogued as COSV100734403; called by muse, mutect2
- KIF21A | c.3405G>A p.T1135= (on ENST00000361418 / NM_001378440.1; = p.T1122= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/162 reads (9%) | catalogued as rs754591024, COSV62777094; called by muse, mutect2, varscan2
- KIF2B | c.96G>T p.V32= | Silent (SNP) | VAF 194/430 reads (45%) | called by muse, mutect2, varscan2
- LRRC40 | c.546A>T p.S182= | Silent (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- MAGEA1 | c.837C>G p.V279= | Silent (SNP) | VAF 73/324 reads (23%) | called by muse, mutect2, varscan2
- MEX3B | c.933T>A p.A311= | Silent (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- MROH2B | c.3957G>C p.L1319= | Silent (SNP) | VAF 51/358 reads (14%) | catalogued as rs757057293, COSV68188714; called by muse, mutect2, varscan2
- NCAPG | c.1944A>G p.Q648= | Silent (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- OPN5 | c.690C>A p.S230= | Silent (SNP) | VAF 44/155 reads (28%) | called by muse, mutect2, varscan2
- OR5B21 | c.630C>T p.V210= | Silent (SNP) | VAF 71/228 reads (31%) | called by muse, mutect2, varscan2
- OR5F1 | c.339C>A p.I113= | Silent (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- PIGR | c.1779G>A p.E593= | Silent (SNP) | VAF 119/424 reads (28%) | called by muse, mutect2, varscan2
- PISD | c.927G>A p.G309= (on ENST00000439502 / NM_001326412.1; = p.G275= on NM_014338.3) | Silent (SNP) | VAF 91/524 reads (17%) | called by muse, mutect2, varscan2
- PKHD1 | c.6294T>C p.T2098= | Silent (SNP) | VAF 71/289 reads (25%) | called by muse, mutect2, varscan2
- PLAC1 | c.150A>G p.V50= | Silent (SNP) | VAF 63/224 reads (28%) | called by muse, mutect2, varscan2
- PRR23C | c.246C>A p.L82= | Silent (SNP) | VAF 120/292 reads (41%) | called by muse, varscan2
- PSMB11 | c.510G>T p.L170= | Silent (SNP) | VAF 46/232 reads (20%) | called by muse, mutect2, varscan2
- PTPN14 | c.2196G>A p.E732= | Silent (SNP) | VAF 74/218 reads (34%) | called by muse, varscan2
- RBFOX1 | c.147G>C p.A49= | Silent (SNP) | VAF 38/199 reads (19%) | catalogued as rs752770034, COSV60957261; called by muse, mutect2, varscan2
- RYR3 | c.8338C>A p.R2780= (on ENST00000389232; = p.R2781= on NM_001036.6) | Silent (SNP) | VAF 49/236 reads (21%) | catalogued as COSV66801402; called by muse, mutect2, varscan2
- SASH3 | c.1038G>A p.P346= | Silent (SNP) | VAF 118/526 reads (22%) | catalogued as rs140005980, COSV100795136; called by muse, mutect2, varscan2
- SCARF1 | c.936C>T p.H312= | Silent (SNP) | VAF 294/607 reads (48%) | catalogued as rs757033579; called by muse, mutect2, varscan2
- SERPINA12 | c.63A>G p.L21= | Silent (SNP) | VAF 75/218 reads (34%) | called by muse, mutect2, varscan2
- SPRY1 | c.921G>A p.L307= | Silent (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- SRPRA | c.1113A>G p.E371= | Silent (SNP) | VAF 85/317 reads (27%) | called by muse, mutect2, varscan2
- SVEP1 | c.5649A>G p.K1883= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs754660862; called by muse, mutect2, varscan2
- TAF1L | c.2244T>C p.P748= | Silent (SNP) | VAF 32/198 reads (16%) | catalogued as rs775997660; called by muse, mutect2, varscan2
- TEDC1 | c.1487G>A p.*496= (on ENST00000392523 / NM_001367178.1; = p.*427= on NM_001134875.1) | Silent (SNP) | VAF 56/156 reads (36%) | called by muse, varscan2
- TOGARAM2 | c.765C>T p.G255= | Silent (SNP) | VAF 15/181 reads (8%) | called by muse, mutect2
- TRIM49B | c.972A>T p.T324= | Silent (SNP) | VAF 30/221 reads (14%) | called by muse, mutect2, varscan2
- TRIO | c.7689G>T p.T2563= | Silent (SNP) | VAF 124/370 reads (34%) | catalogued as COSV100702551; called by muse, mutect2, varscan2
- ZNF814 | c.2055A>G p.E685= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV101457288; called by muse, mutect2, varscan2
- ACBD4 | chr17:45143620 C>T | 3'Flank (SNP) | VAF 76/141 reads (54%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823921 del G | 5'Flank (DEL) | VAF 24/124 reads (19%) | called by mutect2, pindel, varscan2
- AL353804.6 | n.68G>T | RNA (SNP) | VAF 62/221 reads (28%) | called by muse, mutect2, varscan2
- AP1S3 | c.*39_*42del | 3'UTR (DEL) | VAF 7/40 reads (18%) | catalogued as rs200257231; called by pindel, varscan2
- ARMCX4 | c.1039-4043G>A | Intron (SNP) | VAF 4/38 reads (11%) | catalogued as rs782152145, COSV61449103; called by muse, varscan2
- BCLAF3 | c.*27G>T | 3'UTR (SNP) | VAF 30/122 reads (25%) | called by muse, mutect2, varscan2
- C2CD2 | c.1019-23T>A | Intron (SNP) | VAF 29/556 reads (5%) | called by muse, mutect2
- CDK20 | c.*212T>A | 3'UTR (SNP) | VAF 54/403 reads (13%) | called by muse, mutect2, varscan2
- CENPK | c.241+367G>C | Intron (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- CHRND | c.*739T>C | 3'UTR (SNP) | VAF 72/554 reads (13%) | called by muse, mutect2, varscan2
- CUTA | chr6:33418140 A>C | 5'Flank (SNP) | VAF 54/286 reads (19%) | called by muse, mutect2, varscan2
- DCHS2 | n.2336C>A | RNA (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- DDHD1 | chr14:53152754 C>G | 5'Flank (SNP) | VAF 81/335 reads (24%) | called by muse, mutect2, varscan2
- DGKB | c.2126-31377A>T | Intron (SNP) | VAF 67/193 reads (35%) | called by muse, mutect2, varscan2
- EIF3H | c.289+28920G>T | Intron (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- GABRE | c.784+848C>G | Intron (SNP) | VAF 18/96 reads (19%) | called by muse, varscan2
- GABRE | c.784+770C>A | Intron (SNP) | VAF 28/135 reads (21%) | called by muse, varscan2
- GUSBP10 | n.623T>C | RNA (SNP) | VAF 158/550 reads (29%) | called by muse, mutect2, varscan2
- GUSBP10 | n.110T>C | RNA (SNP) | VAF 106/469 reads (23%) | catalogued as rs1424416446; called by muse, mutect2, varscan2
- HERC2P2 | n.332C>A | RNA (SNP) | VAF 35/220 reads (16%) | called by muse, mutect2, varscan2
- HOPX | chr4:56657839 T>C | 5'Flank (SNP) | VAF 28/170 reads (16%) | catalogued as rs371825375; called by muse, mutect2, varscan2
- LHFPL5 | c.-38G>A | 5'UTR (SNP) | VAF 67/288 reads (23%) | catalogued as rs1446234232; called by muse, mutect2, varscan2
- LINC01387 | n.291C>A | RNA (SNP) | VAF 74/278 reads (27%) | called by muse, mutect2, varscan2
- MAMLD1 | c.*227C>A | 3'UTR (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- NDUFA3 | c.10+27G>A | Intron (SNP) | VAF 29/231 reads (13%) | called by muse, mutect2, varscan2
- OR7E5P | n.172G>T | RNA (SNP) | VAF 43/302 reads (14%) | catalogued as rs767057078; called by muse, mutect2, varscan2
- P3H3 | c.1333+15G>A | Intron (SNP) | VAF 80/284 reads (28%) | called by muse, mutect2, varscan2
- PISD | c.*116G>A | 3'UTR (SNP) | VAF 79/453 reads (17%) | called by muse, varscan2
- PRICKLE4 | c.668-185A>G | Intron (SNP) | VAF 74/377 reads (20%) | called by muse, mutect2, varscan2
- PRKCSH | c.1176-46A>C | Intron (SNP) | VAF 109/239 reads (46%) | called by muse, mutect2, varscan2
- RALYL | c.257-68553G>T | Intron (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- RAX | c.290-11C>T | Intron (SNP) | VAF 36/106 reads (34%) | catalogued as rs754911010; called by mutect2, varscan2
- RN7SL106P | chr15:23163947 C>T | 5'Flank (SNP) | VAF 104/1344 reads (8%) | catalogued as rs1171709416; called by muse, mutect2
- RNA5-8SP2 | chr16:34159184 G>A | 5'Flank (SNP) | VAF 57/212 reads (27%) | called by muse, mutect2, varscan2
- SDHA | c.1064+39C>A | Intron (SNP) | VAF 95/353 reads (27%) | called by muse, mutect2, varscan2
- SLC11A2 | c.*1162T>G | 3'UTR (SNP) | VAF 4/26 reads (15%) | catalogued as rs1239951183; called by muse, mutect2
- SLC9B2 | c.-7A>G | 5'UTR (SNP) | VAF 42/106 reads (40%) | catalogued as rs371420168; called by muse, mutect2, varscan2
- SSPOP | n.9970G>T | RNA (SNP) | VAF 63/303 reads (21%) | called by muse, mutect2, varscan2
- TAB1 | c.-11G>A | 5'UTR (SNP) | VAF 109/359 reads (30%) | called by muse, mutect2, varscan2
- TNPO2 | c.*2011G>A | 3'UTR (SNP) | VAF 78/148 reads (53%) | catalogued as rs527784359, COSV63510236; called by muse, mutect2, varscan2
- TRIM51BP | n.956C>G | RNA (SNP) | VAF 60/366 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10361-4591G>C | Intron (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- VAPB | c.*3581C>G | 3'UTR (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- WWOX | c.-106G>T | 5'UTR (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- ZNF48 | chr16:30395313 C>A | 5'Flank (SNP) | VAF 86/286 reads (30%) | called by muse, mutect2, varscan2
